Gene-level copy-number profile of tumor specimen TCGA-P3-A5Q6-01A from TCGA case TCGA-P3-A5Q6, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 49.1 years (17,917 days).
Specimen TCGA-P3-A5Q6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.ef0b1282-421b-4014-a03f-f7f33615c59b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A5Q6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a0733b07-a0e3-4a10-b92c-f19ec82b1849

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 1,860; copy number 2: 26,288; copy number 3: 15,797; copy number 4: 6,014; copy number 5: 6,588; copy number 6: 2,429; copy number 7: 39; copy number 9: 25; copy number 10: 357; copy number 11: 90; copy number 12: 11; copy number 15: 19; copy number 16: 3; copy number 17: 2; copy number 21: 131; copy number 23: 24; copy number 25: 36; copy number 31: 11; copy number 44: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A5Q6-01A-11D-A28Q-01): tumor purity 0.46, ploidy 2.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:214,854–465,259, 1 gene (within-gene range 0–3): DOCK8.
- chr9:452,492–4,587,469, 47 genes (within-gene range 0–2): AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1, AL162419.1, RNU6-694P, SLC1A1.
- chr9:21,929,457–22,128,103, 8 genes (within-gene range 0–2): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,793 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:106,933,739–106,996,534, 1 gene, copy number 5 (within-gene range 4–5): AC005040.2.
- chr2:106,963,193–110,245,420, 68 genes, copy number 5 (broad region; genes not listed).
- chr2:115,468,056–121,809,962, 79 genes, copy number 6 (broad region; genes not listed).
- chr3:93,843,764–140,577,397, 792 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr3:140,619,694–190,716,399, 809 genes, copy number 5–31 (broad region; genes not listed).
- chr4:35,487,812–35,496,003, 2 genes, copy number 12: SEC63P2, RNU6-573P.
- chr4:55,346,242–56,761,485, 39 genes, copy number 7: SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P, EXOC1L, EXOC1, RNU6-652P, AC110611.1, AC110611.2, CEP135, CRACD, RNA5SP161, RNU6-197P, AC022267.1, MRPL22P1, AASDH, RPL7AP31, AC068620.1, PPAT, AC068620.2, AC068620.3, PAICS, SRP72, ARL9, THEGL, GLDCP1, HOPX, AC108215.1, RPL17P20, AC022483.1.
- chr4:72,807,267–89,999,409, 299 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6–16 (broad region; genes not listed).
- chr6:60,281,444–63,779,336, 30 genes, copy number 5–11 (within-gene range 2–11): AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 11: AL354719.1, SCAT8, GCNT1P4.
- chr7:53,002,420–82,657,411, 624 genes, copy number 5–44 (broad region; genes not listed).
- chr7:155,962,632–159,233,377, 50 genes, copy number 6: AC021218.1, Y_RNA, AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1, AC004975.1, AC004975.2, DNAJB6, AC006372.3, AC006372.1, AC006372.2, AC006372.4, PTPRN2, MIR153-2, AC005481.1, AC006003.1, PTPRN2-AS1, AC011899.2, AC011899.3, AC011899.1, MIR595, AC078942.1, LINC01022, MIR5707, THAP5P1, NCAPG2, AC019084.1, ESYT2, DYNC2I1, AC004863.1, LINC00689, VIPR2, AC007269.1, PIP5K1P2.
- chr8:82,033,533–91,398,155, 114 genes, copy number 5 (broad region; genes not listed).
- chr8:125,270,604–128,564,679, 49 genes, copy number 10–25: RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824.
- chr9:105,694,541–123,268,586, 272 genes, copy number 5 (broad region; genes not listed).
- chr11:65,066,300–102,001,062, 905 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:108,957,718–111,889,474, 57 genes, copy number 5: AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715, RDX, TFAMP2, AP001981.2, RPSAP50, AP001981.1, AP001889.1, ZC3H12C, LINC02732, FDX1, ARHGAP20, HNRNPA1P60, AP002963.1, AP003973.4, RNA5SP350, AP003973.2, LINC02550, AP003973.3, RPS17P15, AP003973.1, C11orf53, COLCA1, COLCA2, AP002448.1, MIR4491, POU2AF1, RNU2-60P, AP002008.3, AP002008.2, BTG4, AP002008.4, MIR34B, MIR34C, AP002008.1, HOATZ, LAYN, SIK2, AP000925.1, RN7SKP273, PPP2R1B, AP001781.1, ALG9, AP001781.2, ALG9-IT1, GNG5P3, FDXACB1, C11orf1, RPL37AP8.
- chr11:111,912,734–111,914,093, 1 gene, copy number 5: HSPB2.
- chr12:66,767–34,058,745, 843 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:18,333,726–99,003,545, 1,766 genes, copy number 5 (broad region; genes not listed).
- chr15:19,878,555–48,343,373, 883 genes, copy number 5 (broad region; genes not listed).
- chr16:46,469,341–90,222,851, 1,141 genes, copy number 5–10 (broad region; genes not listed).
- chr18:47,390–6,108,382, 122 genes, copy number 5–6 (broad region; genes not listed).
- chr18:5,956,101–6,017,839, 2 genes, copy number 6: AP001021.2, RNU5F-3P.
- chr19:27,638,483–33,815,763, 132 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,728. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
